Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3525, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3525-01A (Primary Tumor).

*** Diagnosis/Diagnoses: ***

Ileocolonic resection specimen including an extended, extensively ulcerated moderately differentiated adenocarcinoma of the colorectal type localized in the ascending colon with extensive infiltration of the pericolonic fatty tissue and two regional lymph node metastases. Tumor-free large and small bowel resection margins. Tumor-free mesenteric resection margin. Tumor-free appendix. Tumor free omental fat tissue. Small tubular adenoma of the colonic mucosa with slight dysplasia (synonym: low-grade intra-epithelial neoplasia) additionally.

Tumor stage: pT3 pN1 (2/28) pMX; G2, L0, V0 R0.

Source: NCI Genomic Data Commons file 2ea9a1a9-99c7-442d-a4a3-1c67df79ceb0 (TCGA-AA-3525.A97997E2-B3D7-43BC-A519-2AA0AB3DA2CA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).